Somatic mutation profile of tumor specimen MP2PRT-PATBNX-TMP1-A (aliquot MP2PRT-PATBNX-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PATBNX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,632 days).
Specimen MP2PRT-PATBNX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad83d9a1-8b63-4716-b8de-c04285645196.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBNX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBNX-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2fd2cce-0d99-4a2a-aab2-6581929e9f9e

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.2729G>A p.R910H (on ENST00000280772 / NM_001320874.2; = p.R44H on NM_001149.3) | Missense Mutation (SNP) | VAF 143/397 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779132464; called by muse, mutect2, varscan2
- PCDH12 | c.3434C>T p.T1145I | Missense Mutation (SNP) | VAF 216/487 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1191957458, COSV51524275; called by muse, varscan2
- TEX55 | c.1439T>C p.I480T | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs533220309; called by muse, mutect2
- ACTRT1 | c.379T>A p.F127I | Missense Mutation (SNP) | VAF 203/500 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-15 | chr14:106153622 TCT>GTCCCATCGG | Missense Mutation (INS) | VAF 73/99 reads (74%) | called by pindel, varscan2*
- SH3TC1 | c.2726T>G p.F909C | Missense Mutation (SNP) | VAF 236/563 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AGAP3 | c.900G>A p.S300= (on ENST00000622464; = p.S336= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/712 reads (5%) | catalogued as rs754541158, COSV100103829; called by muse, mutect2
- POU3F4 | c.915G>A p.A305= | Silent (SNP) | VAF 147/366 reads (40%) | catalogued as COSV64540760; called by muse, mutect2, varscan2
- TEX37 | c.252C>T p.P84= | Silent (SNP) | VAF 162/409 reads (40%) | catalogued as rs754507953, COSV100304722; called by muse, mutect2, varscan2
- IGHV1-58 | chr14:106627248 ins TCTCTTAAGGGA | 5'Flank (INS) | VAF 18/71 reads (25%) | called by pindel, varscan2
- IGHV4-61 | chr14:106639118 ins TCTCTTAAGGGA | 3'Flank (INS) | VAF 24/51 reads (47%) | called by pindel, varscan2
- OBSCN | c.18662-2010G>A | Intron (SNP) | VAF 256/566 reads (45%) | catalogued as rs372502545, COSV52790563; called by muse, mutect2, varscan2
